Gene-level copy-number profile of tumor specimen TCGA-HD-7832-01A from TCGA case TCGA-HD-7832, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 52.5 years (19,192 days).
Specimen TCGA-HD-7832-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e29722c8-d76e-4353-97a8-180332c42560.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HD-7832-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e2761f3-0d71-4aca-8f68-e55f48f58736

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 22; copy number 2: 3,805; copy number 3: 424; copy number 4: 45,407; copy number 5: 704; copy number 6: 6,346; copy number 7: 15; copy number 8: 742; copy number 9: 792; copy number 10: 44; copy number 11: 1,084; copy number 12: 393; copy number 15: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HD-7832-01A-11D-2128-01): tumor purity 0.73, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:20,388,249–20,390,562, 1 gene: AC116096.1.
- chr13:48,296,162–48,303,661, 1 gene: RB1-DT.
- chr13:48,316,863–48,328,564, 2 genes: PPP1R26P1, PCNPP5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,341 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–65,771,261, 289 genes, copy number 9 (broad region; genes not listed).
- chr8:80,204,606–104,256,094, 435 genes, copy number 9 (broad region; genes not listed).
- chr8:104,339,087–104,356,689, 1 gene, copy number 9 (within-gene range 8–9): DCSTAMP.
- chr8:107,899,316–116,944,487, 66 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr8:117,017,946–117,018,248, 1 gene, copy number 9: RN7SL228P.
- chr9:68,328,308–68,531,061, 1 gene, copy number 11 (within-gene range 5–11): PGM5.
- chr9:68,393,881–138,203,325, 1,370 genes, copy number 10–12 (broad region; genes not listed).
- chr14:20,897,985–22,536,204, 178 genes, copy number 12–15 (within-gene range 6–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
